Somatic mutation profile of tumor specimen C3N-00958-02 (aliquot CPT0384730009) from CPTAC case C3N-00958, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary renal cell carcinoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 67.3 years (24,567 days).
Specimen C3N-00958-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65ac21ba-4b1b-4dc6-80cc-75583811f4e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00958-32 (Blood Derived Normal), aliquot CPT0385460002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c0dacad-525a-4e7e-ab8a-a5cfb26d4a9c

The open-access MAF lists 120 somatic variants for this specimen: 82 protein-altering or splice-affecting, 21 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 21, Intron 11, Frame Shift Ins 6, Frame Shift Del 6, Nonsense Mutation 4, In Frame Del 4, 3'UTR 4, Splice Region 3, 3'Flank 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB10 | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 134/308 reads (44%) | catalogued as rs1301305158, COSV60623325; called by muse, mutect2, varscan2
- ADCY4 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs200743091, COSV60257963; called by muse, mutect2, varscan2
- CTNNA2 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63594691; called by muse, mutect2, varscan2
- CUL7 | c.1717C>A p.L573I | Missense Mutation (SNP) | VAF 178/414 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.067); catalogued as COSV99538803; called by muse, mutect2, varscan2
- DEFB110 | c.171A>G p.I57M | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as COSV64484632; called by mutect2, varscan2
- ELAC2 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 198/683 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs1419763158; called by muse, mutect2, varscan2
- EP300 | c.5926C>T p.P1976S | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs1427345303; called by muse, mutect2, varscan2
- GRIN2D | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.031); catalogued as rs956514019; called by muse, mutect2, varscan2
- IGSF22 | c.110A>G p.E37G | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs756518065; called by muse, mutect2, varscan2
- KDM6A | c.2162C>G p.S721* | Nonsense Mutation (SNP) | VAF 121/154 reads (79%) | catalogued as COSV65038629; called by muse, mutect2, varscan2
- MAP1A | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 113/255 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV55805947, COSV55812598; called by muse, mutect2, varscan2
- PADI1 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 123/288 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.79); catalogued as rs780675324, COSV64938227, COSV64938373; called by muse, mutect2, varscan2
- SMARCA1 | c.3041G>A p.R1014K | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs775629775; called by muse, mutect2, varscan2
- TMEM158 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 43/75 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.624); catalogued as rs1279448099; called by muse, mutect2, varscan2
- TRMU | c.772+1G>A p.X258_splice | Splice Site (SNP) | VAF 124/286 reads (43%) | catalogued as COSV99324657; called by muse, mutect2, varscan2
- UGT2A1 | c.1070A>G p.Q357R | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776187409; called by muse, mutect2, varscan2
- ZDHHC21 | c.476A>G p.Y159C | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs1265109105; called by muse, mutect2
- ACTN3 | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ACTR1A | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- ANKRD13A | c.77A>C p.E26A | Missense Mutation (SNP) | VAF 146/229 reads (64%) | SIFT deleterious (0.05); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- ANKS1B | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 79/123 reads (64%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AP2B1 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 102/176 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- ARHGAP30 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- ARHGEF33 | c.2216A>G p.K739R | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- BAG6 | c.2093C>A p.P698H (on ENST00000676571; = p.P651H on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BCL11B | c.1451T>C p.L484P (on ENST00000357195 / NM_001282237.2; = p.L413P on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 183/427 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BEST1 | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 201/511 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BICC1 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRAF | c.1071del p.F357Lfs*15 | Frame Shift Del (DEL) | VAF 122/264 reads (46%) | called by mutect2, pindel, varscan2
- C6orf136 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 131/298 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- CD274 | c.638_640del p.R213_L214delinsI | In Frame Del (DEL) | VAF 63/125 reads (50%) | called by mutect2, pindel, varscan2
- CGN | c.3431A>G p.Q1144R | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CIB3 | c.48T>G p.Y16* | Nonsense Mutation (SNP) | VAF 119/307 reads (39%) | called by muse, mutect2, varscan2
- CLPTM1 | c.1407del p.V470Cfs*47 | Frame Shift Del (DEL) | VAF 88/257 reads (34%) | called by mutect2, pindel, varscan2
- CRTC2 | c.1129T>G p.L377V | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- EPHB1 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ESPN | c.383G>A p.G128D | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FLNB | c.7299_7302dup p.P2435Nfs*3 | Frame Shift Ins (INS) | VAF 128/378 reads (34%) | called by mutect2, pindel, varscan2
- FNIP1 | c.3056G>A p.S1019N | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FZD4 | c.1418del p.N473Tfs*7 | Frame Shift Del (DEL) | VAF 141/415 reads (34%) | called by mutect2, pindel, varscan2
- GLIS2 | c.359T>C p.L120P | Missense Mutation (SNP) | VAF 147/236 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- GMEB2 | c.101_102insC p.L35Vfs*17 | Frame Shift Ins (INS) | VAF 48/152 reads (32%) | called by mutect2, pindel*, varscan2
- GPR179 | c.4061T>C p.V1354A (on ENST00000621958; = p.V1353A on NM_001004334.4) | Missense Mutation (SNP) | VAF 89/221 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HOXD9 | c.399_407del p.G138_G140del | In Frame Del (DEL) | VAF 37/90 reads (41%) | called by mutect2, pindel, varscan2
- IGSF9B | c.214T>G p.F72V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- KCNC4 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 215/486 reads (44%) | called by muse, mutect2, varscan2
- KMT2A | c.3136del p.T1046Pfs*48 | Frame Shift Del (DEL) | VAF 38/111 reads (34%) | called by mutect2, pindel, varscan2
- LAMP2 | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 53/68 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFAP3L | c.298+3A>T | Splice Region (SNP) | VAF 48/110 reads (44%) | called by muse, varscan2
- MPND | c.1171T>C p.Y391H | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MUS81 | c.1481T>C p.V494A | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH1 | c.2630_2636del p.P877Rfs*300 | Frame Shift Del (DEL) | VAF 152/411 reads (37%) | called by mutect2, pindel, varscan2
- NRIP1 | c.2249T>C p.I750T | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NUP153 | c.2240C>A p.T747K | Missense Mutation (SNP) | VAF 116/255 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PARP10 | c.3-4C>A | Splice Region (SNP) | VAF 96/199 reads (48%) | called by muse, mutect2, varscan2
- PAXIP1 | c.2419G>C p.V807L | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2
- PC | c.1928_1930del p.L643del | In Frame Del (DEL) | VAF 66/184 reads (36%) | called by pindel, varscan2
- PRMT7 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 157/256 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- PRR12 | c.2503_2505del p.K835del (on ENST00000615927; = p.K1656del on NM_020719.3) | In Frame Del (DEL) | VAF 50/172 reads (29%) | called by pindel, varscan2
- PSMB6 | c.14dup p.L5Ffs*39 | Frame Shift Ins (INS) | VAF 90/402 reads (22%) | called by mutect2, pindel, varscan2
- RSAD1 | c.902C>A p.P301H | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSU1 | c.41A>T p.E14V | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN4A | c.3806T>G p.L1269R | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- SIAH1 | c.130T>A p.C44S | Missense Mutation (SNP) | VAF 131/473 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC15A1 | c.310A>T p.N104Y | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- SLC6A3 | c.1125C>G p.H375Q | Missense Mutation (SNP) | VAF 232/501 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- TAAR8 | c.1012dup p.S338Kfs*? | Frame Shift Ins (INS) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- TAS1R1 | c.240dup p.L81Afs*4 | Frame Shift Ins (INS) | VAF 40/118 reads (34%) | called by mutect2, pindel
- TBCC | c.606C>A p.H202Q | Missense Mutation (SNP) | VAF 125/309 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBRG1 | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- TGM2 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 209/336 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBE2A | c.125+6T>C | Splice Region (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- USP8 | c.1588A>T p.S530C | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- UTP4 | c.629dup p.S211Kfs*26 | Frame Shift Ins (INS) | VAF 270/1041 reads (26%) | called by mutect2, pindel, varscan2
- YIF1B | c.914T>C p.M305T (on ENST00000339413 / NM_001039673.3; = p.M290T on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/191 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZBTB41 | c.2116A>G p.R706G | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, varscan2
- ZFAT | c.3071A>G p.N1024S | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZFHX2 | c.5742del p.G1915Afs*15 | Frame Shift Del (DEL) | VAF 130/352 reads (37%) | called by mutect2, pindel, varscan2
- ZNF219 | c.571T>C p.C191R | Missense Mutation (SNP) | VAF 89/172 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZNF575 | c.572A>T p.K191M | Missense Mutation (SNP) | VAF 139/304 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZNF618 | c.931G>T p.V311L (on ENST00000374126 / NM_001318042.2; = p.V279L on NM_001318040.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 125/291 reads (43%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNRF4 | c.647A>G p.E216G | Missense Mutation (SNP) | VAF 154/328 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AIFM3 | c.213T>A p.A71= | Silent (SNP) | VAF 70/153 reads (46%) | catalogued as rs142254599; called by muse, mutect2, varscan2
- ANPEP | c.147C>A p.T49= | Silent (SNP) | VAF 81/180 reads (45%) | called by muse, mutect2, varscan2
- BAZ1B | c.1101A>G p.E367= | Silent (SNP) | VAF 73/114 reads (64%) | called by muse, mutect2, varscan2
- BICC1 | c.1797G>A p.G599= | Silent (SNP) | VAF 37/213 reads (17%) | called by muse, mutect2, varscan2
- CYB561D2 | c.342C>A p.A114= | Silent (SNP) | VAF 89/175 reads (51%) | called by muse, mutect2, varscan2
- DKK2 | c.489G>A p.Q163= | Silent (SNP) | VAF 72/180 reads (40%) | called by muse, mutect2, varscan2
- DMD | c.9067A>C p.R3023= | Silent (SNP) | VAF 147/177 reads (83%) | called by muse, mutect2, varscan2
- DPP8 | c.906A>G p.L302= (on ENST00000341861 / NM_001320875.2; = p.L286= on NM_017743.6) | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs749779466; called by muse, mutect2, varscan2
- HNRNPDL | c.1047A>G p.G349= | Silent (SNP) | VAF 63/129 reads (49%) | called by muse, mutect2, varscan2
- IL17RC | c.1425G>A p.Q475= (on ENST00000295981 / NM_153461.4; = p.Q389= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 79/194 reads (41%) | called by muse, mutect2, varscan2
- INTS9 | c.1239A>C p.G413= | Silent (SNP) | VAF 85/203 reads (42%) | called by muse, mutect2, varscan2
- KBTBD13 | c.621G>T p.L207= | Silent (SNP) | VAF 47/142 reads (33%) | called by muse, mutect2, varscan2
- MAST4 | c.7665C>G p.A2555= (on ENST00000403625 / NM_001164664.2; = p.A2366= on NM_015183.3) | Silent (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- MYOC | c.1170C>T p.V390= | Silent (SNP) | VAF 113/256 reads (44%) | catalogued as COSV50678855; called by muse, mutect2, varscan2
- PCDHA9 | c.2118G>A p.A706= | Silent (SNP) | VAF 202/495 reads (41%) | catalogued as COSV65328491; called by muse, mutect2, varscan2
- SCRIB | c.1515C>G p.P505= | Silent (SNP) | VAF 50/139 reads (36%) | called by muse, mutect2, varscan2
- SLC38A6 | c.1047C>T p.F349= | Silent (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- SLC4A7 | c.972C>T p.S324= | Silent (SNP) | VAF 51/102 reads (50%) | called by muse, mutect2, varscan2
- SPPL2B | c.417C>T p.P139= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as rs768990264, COSV101194565, COSV101194656; called by muse, mutect2, varscan2
- SRSF9 | c.570T>C p.Y190= | Silent (SNP) | VAF 168/324 reads (52%) | called by muse, mutect2, varscan2
- ZNF142 | c.2898C>T p.S966= (on ENST00000411696 / NM_001379660.1; = p.S766= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 91/191 reads (48%) | called by muse, mutect2, varscan2
- BCAP31 | c.-45+393_-45+401del | Intron (DEL) | VAF 87/120 reads (73%) | called by mutect2, pindel, varscan2
- DEPDC5 | c.*854C>T | 3'UTR (SNP) | VAF 159/304 reads (52%) | called by muse, mutect2, varscan2
- EMC2 | c.363+50T>A | Intron (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- FTH1 | c.115-52C>A | Intron (SNP) | VAF 133/363 reads (37%) | called by muse, mutect2, varscan2
- FTH1 | c.115-53G>T | Intron (SNP) | VAF 130/361 reads (36%) | called by muse, mutect2, varscan2
- GDAP1 | c.*683T>G | 3'UTR (SNP) | VAF 49/104 reads (47%) | called by muse, mutect2, varscan2
- HSPA9 | c.1962+14A>T | Intron (SNP) | VAF 145/329 reads (44%) | called by muse, mutect2, varscan2
- MED23 | c.2779-25A>G | Intron (SNP) | VAF 86/201 reads (43%) | catalogued as rs1271362509; called by muse, mutect2, varscan2
- NT5C3A | c.*276G>C | 3'UTR (SNP) | VAF 56/196 reads (29%) | called by muse, mutect2, varscan2
- PGAP2 | c.525+27C>T | Intron (SNP) | VAF 63/148 reads (43%) | called by muse, mutect2, varscan2
- RAPGEF1 | c.1854+2650G>A | Intron (SNP) | VAF 91/205 reads (44%) | catalogued as rs1299140126; called by muse, mutect2, varscan2
- RCC1 | c.-261-657T>G | Intron (SNP) | VAF 133/392 reads (34%) | called by muse, mutect2, varscan2
- RN7SL214P | chr15:77918852 del T | 5'Flank (DEL) | VAF 149/479 reads (31%) | called by mutect2, pindel, varscan2
- RPL7L1P9 | chr2:217756060 T>C | 3'Flank (SNP) | VAF 102/240 reads (43%) | catalogued as rs1301342425; called by muse, mutect2, varscan2
- SRSF5 | c.297-74T>C | Intron (SNP) | VAF 80/201 reads (40%) | called by muse, mutect2, varscan2
- TMEM70 | c.*724A>G | 3'UTR (SNP) | VAF 43/179 reads (24%) | catalogued as rs967129031; called by muse, mutect2, varscan2
- TSGA10 | c.-356+19A>G | Intron (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2
